TCGA case TCGA-FB-A4P6 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9246c642-3231-4137-a24b-3efae151b655

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 54.5 years (19,904 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 767 days (2.1 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 46; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 55 days; Days to treatment end: 96 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 55 days; Days to treatment end: 96 days; Treatment dose: 4,680 cGy; Number of fractions: 26; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 130 days; Days to treatment end: 221 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Oxaliplatin; Days to treatment start: 698 days (1.9 years); Days to treatment end: 726 days (2.0 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Whipple.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS). Age at diagnosis: 56.2 years (20,524 days); Days to diagnosis: 620 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 363 days; Disease response: Tumor Free.
- Day 620 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 620 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 767 days (2.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 7.

Exposures
- Alcohol history: No; Alcohol intensity: Non-Drinker.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1987; Tobacco smoking quit year: 2012.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FB-A4P6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 760 mg.
  Slide TCGA-FB-A4P6-01A-01-TSA: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FB-A4P6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FB-A4P6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tobacco smoking history indicator: 4; Alcohol history documented: Yes; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 4: Pharmaceutical therapy drug name: 5-Fluorouracil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 767 days; disease-specific survival: no event (censored), 767 days; disease-free interval: event (new tumor event after initially disease-free), 620 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 620 days.
